Somatic mutation profile of tumor specimen TARGET-10-PANVDH-09A (aliquot TARGET-10-PANVDH-09A-01D) from TARGET case TARGET-10-PANVDH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,036 days).
Specimen TARGET-10-PANVDH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1155a79-5e6a-42ae-b786-500d0c1a9958.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANVDH-14A (Bone Marrow Normal), aliquot TARGET-10-PANVDH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f2958bf-68ca-4aad-86d8-326e7ec904ac

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 27/102 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1998G>C p.K666N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: likely pathogenic; called by mutect2, varscan2
- ARHGAP39 | c.2296G>A p.V766M | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764235807, COSV52769859; called by muse, mutect2, varscan2
- CATSPERD | c.374C>A p.S125Y | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs370820146, COSV101062622, COSV67534523; called by muse, varscan2
- ABCA5 | c.2090C>T p.S697L | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CELSR2 | c.1725C>G p.F575L | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.09); called by muse, mutect2
- CNTLN | c.3634A>T p.M1212L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2
- IGHV2-26 | chr14:106301395 GT>TGGGGA | Missense Mutation (INS) | VAF 15/30 reads (50%) | called by pindel, varscan2*
- IL10 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2
- CNTN6 | c.1509C>G p.T503= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs992974545, CD1410397; called by muse, mutect2, varscan2
- PLEKHF1 | c.57G>A p.E19= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- PPP1R9A | c.2217C>A p.A739= | Silent (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- AK9 | c.3633+169G>C | Intron (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2
